Surgical pathology report (de-identified scan), TCGA case TCGA-A6-A566, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-A6-A566-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

adenocarcinoma, mucinous, NOS
8480/3

SURGICAL PATHOLOGY REPORT

Site: colon, descending C18.6

SPECIMEN

- A. Apical lymph node
- B. Left hemicolectomy, left nephrectomy, distal pancreas, spleen, proximal jejunum
- C. Appendix

hw 1/4/13

CLINICAL NOTES

CLINICAL HISTORY: Carcinoma descending colon invading hilum left kidney, distal pancreas, segment of jejunum.

GROSS DESCRIPTION

A. The specimen is Received in formalin, labeled "apical lymph node" and consists of a piece of tan and yellow tissue measuring 1.2 x 1 x 0.4 cm. bisected AS-1 after fixation. AS-1.

B. The specimen is received unfixed labeled "left hemicolectomy, left nephrectomy, distal pancreas, spleen, proximal jejunum" and consists of a complex specimen comprising kidney measuring 11 x 7.5 x 5.3 cm., spleen measuring 14 x 7 x 5 cm. and adherent bowel. The bowel measures 33 cm. in length and has stapled margin. There is some omentum on the specimen and there is a small amount of pericolic fat. There are no palpable nodes in the pericolic fat. There is an adherent segment of bowel centrally that might represent small bowel that measures 8 cm. in length and 4 cm. from diameter. The small segment of bowel that looks like it might be adherent to small bowel has fungating tumor centrally. The central tumor mass is adherent to the small bowel and kidney, measures 6.5 cm. in diameter by external palpation of his roughly spherical. A portion of tumor and normal colon are taken for research purposes. Sections through the tumor taken after fixation show carcinoma invading the lower pole of the kidney and a portion of pancreas measuring 7 x 3 x 2 cm.

BLOCK SUMMARY: #B1, 2 - Colonic and small bowel margins of resection; B3 - 7 - colonic tumor; B8, 9 - pancreas; B10, 11 - spleen; B12 - 15 - kidney and ureter; B16 - 18 - pericolic lymph nodes.

C. The specimen is Received in formalin, labeled "appendix" and consists of a tan vermiform appendix measuring 4.7 cm. in length and 0.5 cm. in diameter. The appendix measures 5 x 1.2 x 0.7 cm. AS-2 The tip of the appendix and the proximal end are in block #1. Sections after fixation.

MICROSCOPIC DESCRIPTION

- A. A single lymph node is negative for malignancy.
- B. Tumor type: Colonic adenocarcinoma with areas of mucinous differentiation
- Tumor grade: 2 out of 3
- Tumor size: 7 cm.
- Distance to nearest margin: 14 cm.

[page 2 of 2]
Level of penetration: Carcinoma penetrates through the muscularis propria of the colon into adjacent pancreas and kidney.

Margins of resection: Negative for malignancy
Vascular invasion: There are areas suspicious for lymphatic invasion in pericolic soft tissue.
Host response: Mild chronic inflammation
Attached lymph nodes: Metastatic carcinoma is present in two of thirteen lymph nodes. The largest metastasis is 0.7 cm. in dimension.

pTNM Stage: T4 N1

Other findings: Sections of pancreas, spleen and kidney are otherwise unremarkable. The spleen is not involved by the tumor.

C. Sections of appendix are unremarkable.

DIAGNOSIS

A. Apical lymph node, biopsy:

A single lymph node is negative for malignancy.

B. Left colon, left kidney, distal pancreas, spleen, proximal jejunum, resection:

Moderately differentiated colonic adenocarcinoma.

Note: Carcinoma invades into the adjacent jejunum, kidney and pancreas. Metastatic carcinoma is present in two of thirteen pericolic lymph nodes.

C. Vermiform appendix, resection:

No pathological diagnosis.

--- End Of Report ---

W 11/4/13

11/2/13

11/2/13

2

Source: NCI Genomic Data Commons file 44e13264-a03c-4ff6-8316-94930ddec210 (TCGA-A6-A566.D2679879-72B7-4515-9496-B1FCE87C8571.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).